Somatic mutation profile of tumor specimen TCGA-WB-A81R-01A (aliquot TCGA-WB-A81R-01A-11D-A35I-08) from TCGA case TCGA-WB-A81R, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 56.0 years (20,438 days).
Specimen TCGA-WB-A81R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0a7c862-cf29-4362-b448-5a307f96bc41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WB-A81R-10A (Blood Derived Normal), aliquot TCGA-WB-A81R-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f62a48b-868b-4a6f-bbd9-e2b56cf25e56

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 22/60 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CXXC4 | c.605C>G p.S202C | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1560544401; called by muse, mutect2
- DBF4 | c.598-2A>T p.X200_splice | Splice Site (SNP) | VAF 4/56 reads (7%) | catalogued as COSV55996761; called by muse, mutect2
- DUSP15 | c.629G>T p.G210V | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs1192774966, COSV99640307; called by muse, mutect2, varscan2
- CSTL1 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- PEX5 | c.1082C>T p.A361V (on ENST00000420616; = p.A353V on NM_000319.5) | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- CLPTM1L | c.1101A>G p.A367= | Silent (SNP) | VAF 50/126 reads (40%) | called by muse, mutect2, varscan2
- NUDT6 | c.153C>T p.D51= | Silent (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2
- ZNF672 | c.108C>T p.H36= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as rs984777851; called by muse, mutect2
- HERC2P3 | n.1626C>T | RNA (SNP) | VAF 15/38 reads (39%) | called by muse, mutect2, varscan2
